Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1D8, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1D8-01A (Primary Tumor).

(First Tumor)

Tumor Site:	Ascending Colon		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	None		
Crohn's like reaction	☒ None	☐ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☒ Expansile	☐ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☐ No	☐ Yes	☒ Unknown
Angiolymphatic Invasion:	☐ No	☒ Yes	☐ Unknown
Mutator Phenotype:	☒ No	☐ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	2		
Pathologist Comment:	no nl mucosa		

Source: NCI Genomic Data Commons file dd1bc9a5-02ea-46ca-abcc-614fb00a3819 (TCGA-DM-A1D8.F078AE22-06A2-45CA-A82E-71F7AEFD0312.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).